Somatic mutation profile of tumor specimen TARGET-30-PARYNK-01A (aliquot TARGET-30-PARYNK-01A-01D) from TARGET case TARGET-30-PARYNK, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Intra-abdominal lymph nodes; Age at diagnosis: 6.2 years (2,279 days).
Specimen TARGET-30-PARYNK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0066f34a-29bc-4fff-913b-bc7714234acd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARYNK-10A (Blood Derived Normal), aliquot TARGET-30-PARYNK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29dcd38d-1029-4ab4-a5a3-cf031b7c470a

The open-access MAF lists 32 somatic variants for this specimen: 29 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Frame Shift Ins 2, Silent 2, Nonsense Mutation 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD24 | c.2003G>T p.G668V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV53675178; called by mutect2, varscan2
- ARAP2 | c.2173+1G>A p.X725_splice | Splice Site (SNP) | VAF 10/36 reads (28%) | catalogued as COSV58291361; called by muse, mutect2, varscan2
- ATL3 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as COSV60298062; called by muse, mutect2, varscan2
- CDH5 | c.1184C>G p.A395G | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58519608; called by muse, mutect2, varscan2
- CDH6 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.972); catalogued as COSV54072971, COSV54076964; called by muse, mutect2, varscan2
- EPHA3 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as rs1348993609, COSV60723930; called by mutect2, varscan2
- FAM114A1 | c.1131T>A p.H377Q | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as COSV62674636; called by muse, mutect2, varscan2
- FPGS | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs1333395651, COSV64676186; called by mutect2, varscan2
- GOLIM4 | c.1994G>A p.R665H | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.001); catalogued as rs773783432, COSV58328533; called by mutect2, varscan2
- ITGAX | c.717G>T p.L239F | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV51650687; called by muse, mutect2, varscan2
- KRTAP19-4 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV61859529; called by muse, mutect2, varscan2
- LRCH3 | c.1075G>C p.G359R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV58396020; called by muse, mutect2, varscan2
- LRIF1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV63898315; called by muse, mutect2, varscan2
- MUC16 | c.25028A>G p.E8343G | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as COSV67488892; called by muse, mutect2, varscan2
- NAALADL2 | c.2332G>T p.V778F | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.312); catalogued as COSV71986645; called by muse, mutect2, varscan2
- NLRC3 | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV57095153; called by muse, mutect2, varscan2
- NNT | c.79C>A p.R27S | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV52928956; called by muse, mutect2, varscan2
- OR4C12 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); catalogued as COSV58860942; called by muse, mutect2, varscan2
- PKD1L1 | c.3058C>A p.P1020T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.477); catalogued as COSV56976190; called by mutect2, varscan2
- RAB3IP | c.1416C>A p.F472L (on ENST00000550536 / NM_175623.4; = p.F456L on NM_022456.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV56086306; called by mutect2, varscan2
- SBDS | c.172G>C p.V58L | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV55888553; called by muse, mutect2, varscan2
- SNX20 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56058752; called by mutect2, varscan2
- SREBF1 | c.2276C>T p.A759V | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs529689353, COSV55419487, COSV99888482; called by muse, mutect2, varscan2
- TGM6 | c.709C>A p.Q237K | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV52483726; called by muse, mutect2, varscan2
- TMC4 | c.317G>T p.R106I (on ENST00000617472 / NM_001145303.3; = p.R100I on NM_144686.4) | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV55474923, COSV55477381; called by muse, mutect2, varscan2
- FYCO1 | c.502_513delinsT p.G168* | Frame Shift Del (DEL) | VAF 29/77 reads (38%) | called by pindel, varscan2*
- OR11H4 | c.125dup p.L42Ffs*39 | Frame Shift Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- PPM1D | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.182); called by muse, mutect2
- SLIT2 | c.1017dup p.A340Cfs*20 | Frame Shift Ins (INS) | VAF 20/67 reads (30%) | called by mutect2, pindel, varscan2
- LIMK2 | c.1863G>A p.E621= | Silent (SNP) | VAF 67/218 reads (31%) | catalogued as COSV53224540; called by muse, mutect2, varscan2
- LRRC18 | c.705C>G p.T235= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as COSV53285674; called by muse, mutect2, varscan2
- SNORD116-21 | n.39G>T | RNA (SNP) | VAF 29/147 reads (20%) | called by muse, mutect2, varscan2
